National Lung Screening Trial (NLST) participant 208261 — screening results and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 61 years; Gender: female; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; no CT screening exam record exists for this participant — in this public subset that is the pattern of the chest-radiography arm: every CT screen with a result has an exam record, and the subset has no trial-arm field)
- T0 (day 0): Negative screen, minor abnormalities not suspicious for lung cancer.
- T1: No screening result: Not Expected - Death in screening window.
- T2: No screening result: Not Expected - Death before screening window.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer followed a negative screen; study year of the first confirmed lung cancer: T0; the diagnosis is not linked to a positive screen by the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 86, study year T0. Site: upper lobe of lung (ICD-O-3 C34.1), determined from cytology and histology combined. Primary tumour location: lingula. Histology: small cell carcinoma, NOS (ICD-O-3 8041/3). AJCC 6th edition staging: stage IV (best stage, from pathologic TNM); clinical TX N2 M1 (stage IV); pathologic TX N2 M1 (stage IV). AJCC 7th edition staging: stage IV; clinical TX N2 M1b; pathologic TX N2 M1b. Summary stage: distant.

Follow-up
Last known free of lung cancer: day 86 (for ACRIN participants with lung cancer this field holds the diagnosis date).
